HCMI case HCM-BROD-0472-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf1dca4b-9176-4390-9ba9-6b0bcf3ccf04

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Dead; Days to death: 125 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Small cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8041/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 65.9 years (24,082 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T0; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Brain, NOS / Liver.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 29 days; Days to treatment end: 76 days.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 43 days; Days to treatment end: 48 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/6; ICD-10 code: C79.3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.0 years (24,098 days); Days to diagnosis: 16 days.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 125 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 55.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 176 cm; BMI: 26.1.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 75.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0472-C34-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0472-C34-06B-02-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0472-C34-06B-02-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0472-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0472-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
